Somatic mutation profile of tumor specimen MMRF_2325_1_BM_CD138pos (aliquot MMRF_2325_1_BM_CD138pos_T3_KHS5U_K14009) from MMRF case MMRF_2325, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.0 years (16,421 days).
Specimen MMRF_2325_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d57a87f6-f745-49b9-a24c-291f21595bdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2325_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2325_1_PB_Whole_C3_KHS5U_K14008; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27a6f94a-126a-4e6d-acfd-15ab2f79f5d4

The open-access MAF lists 94 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 23, Silent 10, Intron 9, Nonsense Mutation 5, RNA 3, Splice Site 2, Frame Shift Del 2, In Frame Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH18A1 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 80/182 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64662204; called by muse, mutect2, varscan2
- ANAPC2 | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771127658; called by muse, mutect2, varscan2
- ARHGAP42 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs1000162137, COSV99037759; called by muse, mutect2, varscan2
- CDKAL1 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.067); catalogued as rs779397200, COSV99216584; called by muse, mutect2
- CHST5 | c.167C>A p.P56Q | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV60340797; called by muse, mutect2, varscan2
- CTSO | c.5A>C p.D2A | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV70809300; called by muse, mutect2, varscan2
- DNMT1 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.062); catalogued as COSV100533184; called by muse, mutect2, varscan2
- EIF3A | c.2825A>G p.D942G | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1449190712; called by muse, mutect2, varscan2
- GAPDH | c.129+6_129+19del p.X43_splice | Splice Site (DEL) | VAF 84/234 reads (36%) | catalogued as rs775048305; called by mutect2, varscan2
- GRIP1 | c.2538G>T p.L846F (on ENST00000359742 / NM_001379345.1; = p.L794F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as COSV54041471; called by muse, mutect2, varscan2
- IGHV3-33 | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 154/159 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as rs560208944; called by muse, varscan2
- INHA | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 110/187 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs372427524; called by muse, mutect2, varscan2
- KCNK10 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.398); catalogued as COSV56641288; called by muse, mutect2, varscan2
- KLHL13 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs371548241; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs1238467062, COSV61009717; called by muse, mutect2, varscan2
- NCKAP5 | c.5342G>A p.R1781H | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs755560675; called by muse, mutect2
- PCDHGA4 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as rs746094461, COSV53925110; called by muse, mutect2, varscan2
- SDK1 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 17/153 reads (11%) | catalogued as COSV101268871; called by muse, mutect2, varscan2
- TAS2R1 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.548); catalogued as rs115815829; called by muse, mutect2, varscan2
- TMEM132B | c.655T>G p.F219V | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV100169434; called by muse, mutect2, varscan2
- ZNF536 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750913170, COSV62824867; called by muse, mutect2, varscan2
- AC011005.1 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- AMIGO1 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.144); called by muse, mutect2
- ANKFY1 | c.2194G>A p.A732T (on ENST00000341657 / NM_001330063.2; = p.A733T on NM_016376.5) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL15A1 | c.2409+1G>A p.X803_splice | Splice Site (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- CYLD | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- DAAM1 | c.2741A>G p.K914R | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.124); called by muse, varscan2
- DZIP1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HIP1 | c.1440G>T p.Q480H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- HOMER2 | c.608A>T p.E203V (on ENST00000304231 / NM_199330.3; = p.E192V on NM_004839.4) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- IGHV3-33 | c.123T>A p.C41* | Nonsense Mutation (SNP) | VAF 112/120 reads (93%) | called by muse, varscan2
- KRAS | c.176_178del p.A59del | In Frame Del (DEL) | VAF 20/87 reads (23%) | called by pindel, varscan2
- MALRD1 | c.2731T>C p.Y911H | Missense Mutation (SNP) | VAF 118/260 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYOM2 | c.4324A>G p.I1442V | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- OR1S1 | c.545G>C p.C182S | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDGFRA | c.791T>A p.I264N | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C2G | c.2771del p.C924Lfs*2 (on ENST00000676171; = p.C883Lfs*2 on NM_004570.5) | Frame Shift Del (DEL) | VAF 9/74 reads (12%) | called by mutect2, pindel, varscan2
- PRKD2 | c.1695_1697del p.Y566del | In Frame Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- SCD | c.14_20del p.L5Wfs*44 | Frame Shift Del (DEL) | VAF 32/133 reads (24%) | called by mutect2, pindel, varscan2
- SIAH2 | c.407T>A p.F136Y | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- SLAIN2 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 158/278 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC18A1 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SOAT2 | c.1105A>T p.M369L | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- TMOD3 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- USF3 | c.3387A>T p.Q1129H | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- UTRN | c.6499G>C p.V2167L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS50 | c.1427C>G p.S476* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.1478C>A p.P493H | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.395); called by muse, mutect2
- BMPR1B | c.1011C>T p.N337= | Silent (SNP) | VAF 26/270 reads (10%) | called by muse, mutect2
- BPTF | c.7674C>A p.V2558= | Silent (SNP) | VAF 21/203 reads (10%) | called by muse, mutect2, varscan2
- CBLB | c.2889C>G p.A963= | Silent (SNP) | VAF 65/311 reads (21%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.123C>T p.C41= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as rs377265996; called by muse, varscan2
- IGHV3-33 | c.183C>G p.G61= | Silent (SNP) | VAF 150/156 reads (96%) | catalogued as rs778198429; called by muse, varscan2
- IPO11 | c.351T>C p.A117= | Silent (SNP) | VAF 127/271 reads (47%) | called by muse, mutect2, varscan2
- LRCH2 | c.318C>T p.S106= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV57757505; called by muse, mutect2
- NRBP2 | c.462C>T p.C154= | Silent (SNP) | VAF 7/9 reads (78%) | called by muse, mutect2, varscan2
- SOCS1 | c.48A>G p.A16= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs952718435; called by muse, mutect2, varscan2
- ZFHX4 | c.6945A>G p.K2315= | Silent (SNP) | VAF 165/352 reads (47%) | called by muse, mutect2, varscan2
- ADGRA3 | c.1810-549del | Intron (DEL) | VAF 20/54 reads (37%) | catalogued as rs918278998; called by mutect2, varscan2
- AR | c.*3900G>A | 3'UTR (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- CCDC141 | c.1899+1317A>G | Intron (SNP) | VAF 27/120 reads (23%) | called by muse, mutect2, varscan2
- CDH22 | c.*718C>G | 3'UTR (SNP) | VAF 31/144 reads (22%) | called by muse, mutect2, varscan2
- CHEK1 | c.-20-224T>G | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- COBLL1 | c.*3748A>G | 3'UTR (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- CYP2G1P | n.1108C>T | RNA (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- CYP4B1 | c.323-14G>A | Intron (SNP) | VAF 37/152 reads (24%) | catalogued as rs1557495296; called by muse, mutect2, varscan2
- DKK2 | c.*1858G>T | 3'UTR (SNP) | VAF 21/159 reads (13%) | called by muse, mutect2, varscan2
- DNMT3B | c.*1095C>T | 3'UTR (SNP) | VAF 10/60 reads (17%) | catalogued as rs1216226408, COSV99144050; called by muse, mutect2, varscan2
- EPHA5 | c.*2905T>G | 3'UTR (SNP) | VAF 66/106 reads (62%) | called by muse, mutect2, varscan2
- ERO1B | c.*3030C>A | 3'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- FNBP1L | c.*1491G>A | 3'UTR (SNP) | VAF 58/115 reads (50%) | called by muse, mutect2, varscan2
- GABRA6 | c.*495C>T | 3'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- GNA12 | c.*1321T>G | 3'UTR (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- HSPA9 | c.1411-60T>C | Intron (SNP) | VAF 65/138 reads (47%) | catalogued as rs1161171384; called by muse, mutect2, varscan2
- JPH3 | c.2167-1080C>T | Intron (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
- KPNA5 | c.*45+1369T>G | Intron (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- LINC01588 | n.3574G>T | RNA (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- LIX1 | c.*943G>C | 3'UTR (SNP) | VAF 18/123 reads (15%) | called by muse, mutect2, varscan2
- LRATD1 | c.*2866T>C | 3'UTR (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- MGAT4EP | n.890G>T | RNA (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2, varscan2
- MPP3 | c.*272C>T | 3'UTR (SNP) | VAF 57/126 reads (45%) | called by muse, mutect2, varscan2
- NCAM2 | c.*3731C>T | 3'UTR (SNP) | VAF 13/72 reads (18%) | catalogued as COSV53101875; called by muse, mutect2, varscan2
- NEUROD2 | c.*1291G>C | 3'UTR (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- PRND | c.*2580G>C | 3'UTR (SNP) | VAF 7/155 reads (5%) | called by muse, mutect2
- PRRG3 | c.*1552T>C | 3'UTR (SNP) | VAF 81/84 reads (96%) | called by muse, mutect2, varscan2
- RALGPS1 | c.*3167A>G | 3'UTR (SNP) | VAF 16/102 reads (16%) | catalogued as rs1456430853; called by muse, mutect2, varscan2
- RPL3 | c.366-249G>C | Intron (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2
- RUNX1 | c.*1643_*1648del | 3'UTR (DEL) | VAF 66/150 reads (44%) | called by mutect2, pindel, varscan2
- SLC44A1 | c.*3760G>C | 3'UTR (SNP) | VAF 6/127 reads (5%) | called by muse, mutect2
- SMIM12 | chr1:34855206 G>A | 3'Flank (SNP) | VAF 16/532 reads (3%) | called by muse, mutect2
- SOD3 | c.*162A>G | 3'UTR (SNP) | VAF 59/362 reads (16%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2558+147G>A | Intron (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- UBE2W | c.*4754A>C | 3'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- UBXN7 | c.*3837G>A | 3'UTR (SNP) | VAF 6/10 reads (60%) | catalogued as rs1011273721; called by mutect2, varscan2
